Somatic mutation profile of tumor specimen ALCH-AFJR-TTP1-A (aliquot ALCH-AFJR-TTP1-A-1-0-D-A678-36) from ALCHEMIST case ALCH-AFJR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 82.7 years (30,208 days).
Specimen ALCH-AFJR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab308fe1-3409-443c-9cb3-b94d04308983.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFJR-NB1-A (Blood Derived Normal), aliquot ALCH-AFJR-NB1-A-1-0-D-A678-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74e98933-36ef-4faf-84b3-d4359195993c

The open-access MAF lists 329 somatic variants for this specimen: 222 protein-altering or splice-affecting, 59 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 190, Silent 59, Intron 22, Nonsense Mutation 17, RNA 11, 5'UTR 9, Splice Region 4, Frame Shift Del 4, Splice Site 4, 3'Flank 3, In Frame Del 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5488C>T p.R1830C (on ENST00000358273 / NM_001042492.3; = p.R1809C on NM_000267.3) | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797045139, CM077948, CM092072, CM143435, COSV62203168; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PDCD10 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 35/596 reads (6%) | catalogued as rs1357917630, CM056679, COSV67102800; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 68/117 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52661985, COSV52698075, COSV52994812, COSV53498723; called by muse, mutect2, varscan2
- ACTRT1 | c.608T>A p.F203Y | Missense Mutation (SNP) | VAF 57/89 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs1447878256; called by muse, mutect2, varscan2
- ADH6 | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs374084046; called by muse, mutect2, varscan2
- ADPRH | c.434A>G p.H145R | Missense Mutation (SNP) | VAF 181/557 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs746589265; called by muse, mutect2, varscan2
- AHNAK2 | c.8662G>A p.E2888K | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs771061959; called by muse, mutect2, varscan2
- AMIGO2 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs201958203; called by muse, mutect2, varscan2
- APOA5 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 60/111 reads (54%) | catalogued as rs927429381; called by muse, mutect2, varscan2
- AQP12A | c.245C>A p.P82H | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100538736; called by muse, mutect2, varscan2
- B3GAT2 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100017453; called by muse, mutect2, varscan2
- BID | c.710G>C p.R237T (on ENST00000317361 / NM_197966.2; = p.R191T on NM_001196.4) | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58006095; called by muse, mutect2, varscan2
- BNC2 | c.2624G>T p.R875L | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs565215420, COSV66147924; called by muse, mutect2, varscan2
- BRAF | c.1861A>T p.N621Y (on ENST00000288602 / NM_001374244.1; = p.N581Y on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 259/433 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as CM060878, COSV56062673, COSV56077649, COSV56286119; called by muse, mutect2, varscan2
- BTBD11 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 63/210 reads (30%) | catalogued as COSV55031141; called by muse, mutect2, varscan2
- CC2D1A | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1033546846; called by muse, mutect2
- CCDC50 | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 115/535 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as COSV66667169; called by muse, mutect2, varscan2
- CCR1 | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56123155; called by muse, mutect2, varscan2
- CD248 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs775201517; called by muse, mutect2, varscan2
- CDH5 | c.1290G>C p.E430D | Missense Mutation (SNP) | VAF 21/860 reads (2%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV100438919; called by muse, mutect2
- CDH7 | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV59883062; called by muse, mutect2, varscan2
- CLEC4F | c.639C>A p.H213Q | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.554); catalogued as COSV55479243; called by muse, mutect2, varscan2
- CMYA5 | c.6701C>T p.A2234V | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as COSV71408663, COSV71409957; called by muse, mutect2, varscan2
- CPED1 | c.1709C>A p.T570K | Missense Mutation (SNP) | VAF 133/232 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV100120353; called by muse, mutect2, varscan2
- CSMD3 | c.2911C>A p.P971T (on ENST00000297405 / NM_001363185.1; = p.P867T on NM_052900.3) | Missense Mutation (SNP) | VAF 191/497 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52167216, COSV52288444; called by muse, mutect2, varscan2
- CUL9 | c.4262G>A p.R1421Q | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs1299303442, COSV99335359; called by muse, mutect2
- CYP27B1 | c.721T>C p.W241R | Missense Mutation (SNP) | VAF 132/403 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs1261436439, COSV56983757; called by muse, mutect2, varscan2
- DCLRE1C | c.1009G>A p.A337T (on ENST00000378278 / NM_001350965.2; = p.A222T on NM_022487.4) | Missense Mutation (SNP) | VAF 48/506 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs768393244, COSV100739954; called by muse, mutect2
- DNAH1 | c.3915G>T p.K1305N | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV70230371; called by muse, mutect2, varscan2
- DNAH2 | c.8120C>T p.T2707M | Missense Mutation (SNP) | VAF 107/224 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs777943335, COSV104430301; called by muse, mutect2, varscan2
- EIF2AK2 | c.1282G>T p.V428L | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV51797593; called by muse, mutect2, varscan2
- EPHA3 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV60708175; called by muse, mutect2
- ESRRB | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1388735708; called by muse, mutect2, varscan2
- EXOC3 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 76/635 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.044); catalogued as COSV59267312; called by muse, mutect2, varscan2
- FAM170B | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs1196785528, COSV100308476; called by muse, mutect2
- FAM91A1 | c.1810G>T p.G604W | Missense Mutation (SNP) | VAF 254/451 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100593838; called by muse, mutect2, varscan2
- FCGBP | c.4569G>T p.R1523S | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs782130171, COSV55441830; called by muse, mutect2, varscan2
- FIBCD1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1052381227; called by muse, mutect2, varscan2
- FLG | c.7423G>A p.G2475R | Missense Mutation (SNP) | VAF 101/354 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs1183149624, COSV64250568; called by muse, mutect2, varscan2
- FLI1 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 115/219 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs1355289095, COSV61379989; called by muse, mutect2, varscan2
- GNAT1 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 52/193 reads (27%) | catalogued as COSV51699105; called by muse, mutect2, varscan2
- GPR26 | c.401C>A p.A134E | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV52932660; called by muse, mutect2, varscan2
- HACD2 | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as rs1230101731; called by muse, mutect2, varscan2
- HGF | c.1289C>A p.P430Q | Missense Mutation (SNP) | VAF 188/338 reads (56%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.776); catalogued as COSV55955016; called by muse, mutect2, varscan2
- IREB2 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 93/360 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.739); catalogued as COSV99359083; called by muse, mutect2, varscan2
- JAG2 | c.1888G>T p.G630C | Missense Mutation (SNP) | VAF 123/405 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59309272; called by muse, mutect2, varscan2
- LAMB3 | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781198655; called by muse, mutect2
- LARS2 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 31/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1203564287, COSV55532469; called by muse, mutect2, varscan2
- LMOD3 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 109/412 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761915768; called by muse, mutect2, varscan2
- LRP1B | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs776835227; called by muse, mutect2, varscan2
- NEDD4L | c.1634A>G p.N545S (on ENST00000400345 / NM_001144967.3; = p.N525S on NM_015277.6) | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs773924900; called by muse, mutect2, varscan2
- NELL1 | c.1652A>G p.D551G | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs961885972; called by muse, mutect2, varscan2
- NETO1 | c.1403C>A p.P468Q | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.001); catalogued as COSV55007264; called by muse, mutect2, varscan2
- NKG7 | c.71G>C p.S24T | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV52468244; called by muse, mutect2, varscan2
- NWD2 | c.1762G>T p.V588F | Missense Mutation (SNP) | VAF 110/353 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs377678499; called by muse, mutect2, varscan2
- OBSCN | c.3637C>T p.R1213C | Missense Mutation (SNP) | VAF 78/334 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); catalogued as rs367554644; called by muse, mutect2, varscan2
- OR52B6 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV61447135; called by muse, mutect2, varscan2
- OR5H15 | c.326C>A p.T109N | Missense Mutation (SNP) | VAF 94/352 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as rs1314550139, COSV62947363; called by muse, mutect2, varscan2
- OR6N1 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.821); catalogued as COSV58650819; called by muse, mutect2, varscan2
- PEAR1 | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.257); catalogued as COSV52773788; called by muse, mutect2, varscan2
- PEX5 | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 150/499 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1011369978; called by muse, mutect2, varscan2
- PGR | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 133/224 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54800959; called by muse, mutect2, varscan2
- POLD2 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs771866675; called by muse, mutect2, varscan2
- RCBTB2 | c.121_123del p.E41del | In Frame Del (DEL) | VAF 66/204 reads (32%) | catalogued as rs753811771; called by pindel, varscan2
- RHCG | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51516606; called by muse, mutect2, varscan2
- ROS1 | c.2677G>T p.G893C | Missense Mutation (SNP) | VAF 98/527 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778372043; called by muse, mutect2, varscan2
- ROS1 | c.1087dup p.Y363Lfs*25 | Frame Shift Ins (INS) | VAF 62/204 reads (30%) | catalogued as rs1392239785; called by mutect2, pindel, varscan2
- RYR3 | c.1484A>G p.Y495C | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1208407456, COSV101212794; called by muse, mutect2, varscan2
- SERPINB13 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV54028396; called by muse, mutect2, varscan2
- SIPA1L1 | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 78/274 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs764620692; called by muse, mutect2, varscan2
- SKOR2 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 137/315 reads (43%) | SIFT deleterious, low confidence (0); catalogued as COSV71111802; called by muse, mutect2, varscan2
- SLC17A6 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as COSV54141025; called by muse, mutect2, varscan2
- SMARCAL1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 119/284 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1315060813; called by muse, mutect2, varscan2
- SOX5 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV58632985; called by muse, mutect2, varscan2
- SPATA17 | c.943G>C p.G315R | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as rs757995524; called by muse, mutect2, varscan2
- STK11 | c.568del p.L190Sfs*97 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as CM144213; called by mutect2, pindel
- TMOD1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52251299; called by muse, mutect2, varscan2
- TOX2 | c.1040G>T p.R347L (on ENST00000358131 / NM_001098798.2; = p.R323L on NM_032883.3) | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV100364742, COSV57887462; called by muse, mutect2, varscan2
- TREML4 | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 99/393 reads (25%) | catalogued as COSV58384808; called by muse, mutect2
- TRIM48 | c.109T>G p.Y37D | Missense Mutation (SNP) | VAF 163/281 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV70161271; called by muse, varscan2
- TRIM58 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs746407893, COSV63572072, COSV63572248; called by muse, mutect2, varscan2
- ZIC2 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs543003846, COSV66254675; called by muse, mutect2, varscan2
- ZIC4 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 145/460 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101268213; called by muse, mutect2, varscan2
- ZNF34 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs751570665, COSV58638578; called by muse, mutect2, varscan2
- ZNF835 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as COSV73379615; called by muse, mutect2
- ADAMTS16 | c.1077C>A p.D359E | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHNAK2 | c.13613A>T p.E4538V | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2
- AKAP11 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ALPK2 | c.1178C>A p.P393H | Missense Mutation (SNP) | VAF 232/491 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ALS2 | c.3210G>T p.K1070N | Missense Mutation (SNP) | VAF 156/676 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ANKEF1 | c.1513C>A p.L505M | Missense Mutation (SNP) | VAF 42/1211 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.035); called by muse, mutect2
- APOBEC3C | c.455-5_455delinsTTTTTT p.X152_splice | Splice Site (ONP) | VAF 6/71 reads (8%) | called by mutect2*, pindel
- ARHGEF15 | c.1836C>G p.I612M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- ASH1L | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 44/139 reads (32%) | called by muse, mutect2, varscan2
- ASPG | c.1616A>T p.H539L | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN2 | c.3631G>T p.G1211W (on ENST00000313400 / NM_001365069.1; = p.G1160W on NM_014010.5) | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8B4 | c.3007G>A p.V1003I | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BBS12 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.435); called by muse, mutect2
- CCBE1 | c.569A>T p.E190V | Missense Mutation (SNP) | VAF 97/454 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CCDC168 | c.17519G>A p.C5840Y | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- CCDC81 | c.611C>A p.P204H (on ENST00000445632 / NM_001156474.2; = p.P114H on NM_021827.4) | Missense Mutation (SNP) | VAF 136/271 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCR3 | c.977G>T p.R326I | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2
- CDC37L1 | c.736C>A p.Q246K | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CDH10 | c.2023C>G p.L675V | Missense Mutation (SNP) | VAF 32/824 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CENPA | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 83/420 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- CFAP44 | c.3914G>T p.G1305V | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- CFAP47 | c.529del p.A177Qfs*28 | Frame Shift Del (DEL) | VAF 36/76 reads (47%) | called by mutect2, pindel, varscan2
- CFH | c.1067A>T p.Y356F | Missense Mutation (SNP) | VAF 139/501 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- CLIP4 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CNTNAP5 | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 55/157 reads (35%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.3287C>A p.A1096D | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- COL12A1 | c.8178+2T>C p.X2726_splice | Splice Site (SNP) | VAF 63/189 reads (33%) | called by muse, mutect2, varscan2
- COL4A2 | c.4348G>C p.G1450R | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CXCR4 | c.379C>A p.L127M | Missense Mutation (SNP) | VAF 100/410 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYP2R1 | c.746A>T p.N249I | Missense Mutation (SNP) | VAF 157/298 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- DHX34 | c.2207G>T p.R736L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHB6 | c.1219G>C p.V407L | Missense Mutation (SNP) | VAF 173/289 reads (60%) | SIFT tolerated (0.43); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ESR2 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | called by muse, varscan2
- EVC2 | c.3472G>A p.G1158R | Missense Mutation (SNP) | VAF 56/207 reads (27%) | called by muse, mutect2, varscan2
- EYS | c.4901A>C p.K1634T | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.245); called by muse, mutect2
- EYS | c.4156G>T p.D1386Y | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); called by mutect2, varscan2
- FOCAD | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GDA | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- GSAP | c.1996A>T p.N666Y | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2
- HABP2 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC1 | c.1226A>G p.E409G | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HMCN1 | c.10853-2A>G p.X3618_splice | Splice Site (SNP) | VAF 95/405 reads (23%) | called by muse, varscan2
- HSPG2 | c.4314G>T p.T1438= | Splice Region (SNP) | VAF 120/409 reads (29%) | called by muse, mutect2, varscan2
- IGSF1 | c.3388G>T p.G1130W | Missense Mutation (SNP) | VAF 120/210 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL1RL2 | c.927T>A p.D309E | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KCNJ12 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- KCNJ3 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 61/167 reads (37%) | called by muse, mutect2, varscan2
- KEAP1 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- KLHL40 | c.1577C>A p.S526Y | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- KNL1 | c.3822T>G p.H1274Q (on ENST00000346991 / NM_170589.5; = p.H1248Q on NM_144508.5) | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LCN2 | c.475G>T p.G159W | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIMA1 | c.1717C>G p.L573V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- LMBRD2 | c.1621T>A p.C541S | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRPPRC | c.3481G>A p.V1161I | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2
- LRRTM4 | c.-80C>T | Splice Region (SNP) | VAF 62/229 reads (27%) | called by muse, mutect2, varscan2
- MALRD1 | c.5364G>T p.K1788N | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- MAS1 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- MFF | c.815A>C p.Y272S | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- MTO1 | c.272G>T p.R91M | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTO1 | c.273G>T p.R91S | Missense Mutation (SNP) | VAF 77/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MTURN | c.79A>T p.T27S | Missense Mutation (SNP) | VAF 141/357 reads (39%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MYC | c.668T>C p.L223P (on ENST00000377970; = p.L238P on NM_002467.6) | Missense Mutation (SNP) | VAF 150/216 reads (69%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYOM1 | c.575C>A p.A192E | Missense Mutation (SNP) | VAF 106/359 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYPN | c.1402T>C p.W468R | Missense Mutation (SNP) | VAF 266/618 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEK9 | c.2400C>A p.N800K | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NFAM1 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- NFASC | c.1759C>T p.Q587* (on ENST00000339876 / NM_001378329.1; = p.Q598* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 41/161 reads (25%) | called by muse, mutect2, varscan2
- NOXO1 | c.559C>A p.Q187K (on ENST00000397280 / NM_172168.3; = p.Q181K on NM_144603.4) | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- OGA | c.2112G>T p.Q704H | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OLFML2B | c.641G>A p.C214Y | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- OPLAH | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR51V1 | c.171C>A p.S57R | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PCDHA5 | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 138/382 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA5 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PGC | c.58_66del p.I20_K22del | In Frame Del (DEL) | VAF 52/238 reads (22%) | called by pindel, varscan2
- PLSCR2 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PMP22 | c.319+6T>C | Splice Region (SNP) | VAF 16/441 reads (4%) | called by muse, mutect2
- POTEG | c.1056-2A>T p.X352_splice | Splice Site (SNP) | VAF 72/586 reads (12%) | called by muse, mutect2, varscan2
- PRRC2A | c.49T>C p.Y17H | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSG3 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.684); called by muse, mutect2
- PSME4 | c.462T>G p.Y154* | Nonsense Mutation (SNP) | VAF 48/220 reads (22%) | called by muse, mutect2, varscan2
- PTPRF | c.1586A>T p.Q529L | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRZ1 | c.2266G>T p.E756* | Nonsense Mutation (SNP) | VAF 120/225 reads (53%) | called by muse, mutect2, varscan2
- QRICH2 | c.3815G>A p.G1272D | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RAB5C | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RALGAPA1 | c.5156A>G p.N1719S | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by mutect2, varscan2
- RECQL4 | c.1261A>G p.S421G | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- REG3A | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHCG | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 74/336 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- RP1L1 | c.6196G>A p.E2066K | Missense Mutation (SNP) | VAF 115/202 reads (57%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- RXRG | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- RYR1 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 143/281 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SAP130 | c.3128A>T p.K1043M | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- SARAF | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SERPINE3 | c.63C>A p.H21Q | Missense Mutation (SNP) | VAF 119/240 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SEZ6L | c.654G>T p.R218S | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- SF3B1 | c.550G>C p.V184L | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SGCE | c.367T>A p.F123I (on ENST00000647096; = p.F87I on NM_003919.3) | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH3TC2 | c.1407del p.I470Yfs*54 | Frame Shift Del (DEL) | VAF 132/353 reads (37%) | called by mutect2, pindel, varscan2
- SHISA9 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 121/235 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- SLC4A1AP | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 59/322 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SNAPC4 | c.488A>T p.E163V | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SPEF2 | c.3440C>A p.T1147K | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.081); called by muse, varscan2
- SPR | c.250C>A p.R84S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SPTB | c.3352C>T p.Q1118* | Nonsense Mutation (SNP) | VAF 130/542 reads (24%) | called by muse, mutect2, varscan2
- STK33 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 99/192 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- STOML1 | c.664G>C p.V222L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.382); called by muse, mutect2
- SYNE1 | c.2384A>T p.Q795L (on ENST00000367255 / NM_182961.4; = p.Q802L on NM_033071.3) | Missense Mutation (SNP) | VAF 134/376 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TCHH | c.4849C>A p.R1617S | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- TENM2 | c.1717G>A p.V573M (on ENST00000518659 / NM_001122679.2; = p.V341M on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.855); called by muse, mutect2
- TEX13C | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TEX14 | c.3593G>A p.C1198Y (on ENST00000240361 / NM_001201457.2; = p.C1152Y on NM_031272.5) | Missense Mutation (SNP) | VAF 191/349 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TFAP2D | c.46C>A p.H16N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- TJP3 | c.235A>C p.K79Q | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TMEM200C | c.446T>A p.V149E | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- TMPRSS5 | c.106+5G>T | Splice Region (SNP) | VAF 36/61 reads (59%) | called by muse, mutect2, varscan2
- TP63 | c.1940G>T p.R647L | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM10 | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TRPA1 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 152/577 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TTN | c.50459C>G p.A16820G (on ENST00000591111; = p.A9396G on NM_003319.4) | Missense Mutation (SNP) | VAF 21/111 reads (19%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBR4 | c.433A>T p.R145* | Nonsense Mutation (SNP) | VAF 77/354 reads (22%) | called by muse, mutect2, varscan2
- UGT1A3 | c.119A>G p.H40R | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- USP18 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 197/288 reads (68%) | called by muse, mutect2, varscan2
- VCAN | c.4291C>A p.R1431S | Missense Mutation (SNP) | VAF 96/269 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- VPS13B | c.8332A>T p.N2778Y | Missense Mutation (SNP) | VAF 174/333 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- VWDE | c.2546G>C p.S849T | Missense Mutation (SNP) | VAF 154/457 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WASF2 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 139/511 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- WDR1 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- WDR26 | c.1702G>A p.G568R (on ENST00000414423 / NM_001379403.1; = p.G468R on NM_025160.7) | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- WNK1 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- XIRP2 | c.100G>T p.G34C (on ENST00000628543; = p.G209C on NM_152381.6) | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF14 | c.1241C>T p.T414I | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF362 | c.795del p.N266Tfs*121 | Frame Shift Del (DEL) | VAF 92/348 reads (26%) | called by mutect2, pindel, varscan2
- ZNF585B | c.752T>C p.F251S | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF713 | c.518C>T p.A173V (on ENST00000633730 / NM_001366796.2; = p.A186V on NM_182633.3) | Missense Mutation (SNP) | VAF 111/310 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF716 | c.30C>A p.S10R | Missense Mutation (SNP) | VAF 137/453 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ZP4 | c.61C>A p.H21N | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AGTPBP1 | c.2376T>C p.N792= (on ENST00000357081 / NM_001330701.2; = p.N752= on NM_015239.2) | Silent (SNP) | VAF 17/216 reads (8%) | called by muse, mutect2
- AK2 | c.75G>T p.G25= | Silent (SNP) | VAF 122/340 reads (36%) | catalogued as COSV61469839; called by muse, mutect2, varscan2
- ANKRD55 | c.834C>A p.A278= | Silent (SNP) | VAF 57/105 reads (54%) | called by muse, mutect2, varscan2
- AR | c.2406C>A p.P802= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as rs1381286757; called by muse, mutect2, varscan2
- ARMC5 | c.885G>T p.R295= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as CX156835; called by muse, mutect2, varscan2
- C4orf54 | c.2223C>A p.V741= | Silent (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- CFAP91 | c.1470A>G p.E490= | Silent (SNP) | VAF 62/206 reads (30%) | called by muse, mutect2, varscan2
- CHRNA3 | c.585C>A p.S195= | Silent (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- COL11A1 | c.2452C>A p.R818= | Silent (SNP) | VAF 93/342 reads (27%) | catalogued as CM153167; called by muse, mutect2, varscan2
- COL27A1 | c.5508C>T p.I1836= | Silent (SNP) | VAF 17/385 reads (4%) | called by muse, mutect2
- CYP11B2 | c.462G>A p.V154= | Silent (SNP) | VAF 164/293 reads (56%) | catalogued as COSV59996156; called by muse, mutect2, varscan2
- DNAH2 | c.1383T>G p.R461= | Silent (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- DPEP3 | c.981G>T p.L327= | Silent (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- DYRK4 | c.18C>A p.L6= | Silent (SNP) | VAF 46/153 reads (30%) | catalogued as COSV50541493; called by muse, mutect2, varscan2
- FAM114A1 | c.1434A>T p.P478= | Silent (SNP) | VAF 70/234 reads (30%) | called by muse, mutect2, varscan2
- FAM78B | c.477G>T p.L159= | Silent (SNP) | VAF 36/101 reads (36%) | called by muse, mutect2, varscan2
- GABRA5 | c.951C>A p.A317= | Silent (SNP) | VAF 49/208 reads (24%) | called by muse, mutect2, varscan2
- GMDS | c.1062G>T p.L354= | Silent (SNP) | VAF 47/234 reads (20%) | called by muse, mutect2, varscan2
- ITIH5 | c.750C>A p.A250= | Silent (SNP) | VAF 56/187 reads (30%) | called by muse, mutect2, varscan2
- KCNK1 | c.78G>C p.L26= | Silent (SNP) | VAF 82/250 reads (33%) | catalogued as COSV100785836; called by muse, mutect2, varscan2
- KHSRP | c.759G>T p.G253= | Silent (SNP) | VAF 45/88 reads (51%) | called by muse, mutect2, varscan2
- KLF1 | c.681C>A p.P227= | Silent (SNP) | VAF 71/166 reads (43%) | catalogued as rs899654024; called by muse, mutect2, varscan2
- KLHL29 | c.273G>T p.A91= | Silent (SNP) | VAF 32/186 reads (17%) | catalogued as COSV101526528; called by muse, mutect2, varscan2
- KRT31 | c.42C>T p.T14= | Silent (SNP) | VAF 76/114 reads (67%) | called by muse, mutect2, varscan2
- KRTAP13-1 | c.516T>C p.Y172= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs1343705537; called by muse, mutect2, varscan2
- LPA | c.5340C>A p.P1780= | Silent (SNP) | VAF 85/407 reads (21%) | catalogued as COSV60296249; called by muse, mutect2, varscan2
- MAP1A | c.7278C>T p.A2426= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100288731; called by muse, mutect2, varscan2
- MAP4K4 | c.2028C>T p.G676= (on ENST00000347699 / NM_001242559.2; = p.G591= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/245 reads (6%) | called by muse, mutect2
- NPW | c.342G>T p.A114= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs764793237; called by muse, mutect2, varscan2
- NRXN1 | c.3786C>A p.P1262= | Silent (SNP) | VAF 105/379 reads (28%) | called by muse, mutect2, varscan2
- OR2G6 | c.591A>G p.A197= | Silent (SNP) | VAF 69/264 reads (26%) | catalogued as COSV58574865; called by muse, mutect2, varscan2
- OR52W1 | c.174C>A p.S58= | Silent (SNP) | VAF 105/169 reads (62%) | called by muse, mutect2, varscan2
- OR5H15 | c.327C>A p.T109= | Silent (SNP) | VAF 92/349 reads (26%) | called by muse, mutect2, varscan2
- OTOGL | c.4543C>A p.R1515= (on ENST00000547103; = p.R1506= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 67/207 reads (32%) | catalogued as COSV54015370; called by muse, mutect2, varscan2
- PCDH19 | c.2262G>A p.E754= | Silent (SNP) | VAF 142/204 reads (70%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1386G>A p.E462= | Silent (SNP) | VAF 158/363 reads (44%) | catalogued as COSV50763122; called by muse, mutect2, varscan2
- PCDHGA9 | c.1965G>C p.S655= | Silent (SNP) | VAF 117/188 reads (62%) | catalogued as COSV99541415; called by muse, mutect2, varscan2
- POTEJ | c.2895C>T p.G965= | Silent (SNP) | VAF 55/474 reads (12%) | called by muse, mutect2, varscan2
- PPARD | c.801C>T p.I267= | Silent (SNP) | VAF 73/386 reads (19%) | called by muse, mutect2, varscan2
- PPP3CB | c.948G>T p.S316= | Silent (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- PROM2 | c.339G>T p.A113= | Silent (SNP) | VAF 89/224 reads (40%) | called by muse, mutect2, varscan2
- PTPN11 | c.1371G>A p.V457= | Silent (SNP) | VAF 74/217 reads (34%) | called by muse, mutect2, varscan2
- RAG2 | c.30T>C p.N10= | Silent (SNP) | VAF 148/278 reads (53%) | catalogued as COSV57557090; called by muse, mutect2, varscan2
- ROBO1 | c.369G>T p.P123= | Silent (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- RUNX1T1 | c.1663C>T p.L555= (on ENST00000265814 / NM_001198628.1; = p.L528= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 123/645 reads (19%) | called by muse, mutect2, varscan2
- SDK1 | c.3216C>A p.A1072= | Silent (SNP) | VAF 80/193 reads (41%) | called by muse, mutect2, varscan2
- SLC17A6 | c.345C>A p.A115= | Silent (SNP) | VAF 68/203 reads (33%) | catalogued as COSV54137088; called by muse, mutect2, varscan2
- SLIT2 | c.2754G>A p.K918= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as COSV56587307; called by muse, mutect2
- STK36 | c.3459G>A p.L1153= | Silent (SNP) | VAF 61/165 reads (37%) | called by muse, mutect2, varscan2
- STYXL2 | c.2895G>A p.S965= | Silent (SNP) | VAF 85/312 reads (27%) | catalogued as rs201251775, COSV99608401; called by muse, mutect2, varscan2
- SYCP1 | c.2622C>A p.P874= | Silent (SNP) | VAF 21/129 reads (16%) | catalogued as COSV101051204; called by muse, mutect2, varscan2
- TAMALIN | c.111G>T p.P37= | Silent (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- TAS2R1 | c.813T>A p.S271= | Silent (SNP) | VAF 32/160 reads (20%) | called by muse, varscan2
- TMC2 | c.840G>C p.L280= | Silent (SNP) | VAF 85/152 reads (56%) | called by muse, mutect2, varscan2
- TRAK1 | c.405G>A p.S135= (on ENST00000327628 / NM_001349247.2; = p.S77= on NM_014965.5) | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as rs141558684; called by muse, mutect2, varscan2
- TSHR | c.1591C>A p.R531= | Silent (SNP) | VAF 78/304 reads (26%) | catalogued as CM106708, COSV53319151, COSV53328837; called by muse, mutect2, varscan2
- VGF | c.885C>A p.R295= | Silent (SNP) | VAF 20/30 reads (67%) | called by muse, mutect2, varscan2
- ZNF280C | c.1032G>A p.Q344= | Silent (SNP) | VAF 55/98 reads (56%) | catalogued as rs1030083620, COSV63969689; called by muse, mutect2, varscan2
- ZNF518B | c.747G>A p.R249= | Silent (SNP) | VAF 54/292 reads (18%) | called by muse, mutect2, varscan2
- AC006305.1 | n.719del | RNA (DEL) | VAF 33/95 reads (35%) | called by mutect2, pindel, varscan2
- AC092675.1 | n.474A>T | RNA (SNP) | VAF 53/247 reads (21%) | called by muse, mutect2, varscan2
- ACP4 | chr19:50799455 C>A | 3'Flank (SNP) | VAF 32/47 reads (68%) | called by muse, mutect2, varscan2
- ADAM1A | n.848G>C | RNA (SNP) | VAF 101/260 reads (39%) | called by muse, mutect2, varscan2
- AL109984.1 | chr20:52098497 G>A | 3'Flank (SNP) | VAF 138/249 reads (55%) | catalogued as rs1373957786; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915608 G>T | 5'Flank (SNP) | VAF 56/236 reads (24%) | catalogued as COSV100388176; called by muse, mutect2, varscan2
- ARPP19 | c.-69_-45del | 5'UTR (DEL) | VAF 36/168 reads (21%) | called by mutect2, pindel
- CACNB1 | c.-43C>T | 5'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- CCL4 | c.-10C>A | 5'UTR (SNP) | VAF 15/446 reads (3%) | called by muse, mutect2
- CD33 | c.37+13G>T | Intron (SNP) | VAF 36/57 reads (63%) | catalogued as rs367818620; called by muse, mutect2, varscan2
- CDC73 | c.-51G>T | 5'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- CEP120 | c.464-4436C>G | Intron (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- CEP128 | c.1209+894A>T | Intron (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- CHL1 | c.-23G>T | 5'UTR (SNP) | VAF 54/170 reads (32%) | called by muse, mutect2, varscan2
- CLRN1 | c.433+44T>C | Intron (SNP) | VAF 60/222 reads (27%) | called by muse, mutect2, varscan2
- DCN | c.211+5617G>T | Intron (SNP) | VAF 85/244 reads (35%) | called by muse, mutect2, varscan2
- DYRK4 | c.-64C>T | 5'UTR (SNP) | VAF 32/163 reads (20%) | catalogued as rs71579236; called by muse, mutect2, varscan2
- DYTN | c.-27C>A | 5'UTR (SNP) | VAF 25/127 reads (20%) | catalogued as COSV71751562, COSV71753210; called by muse, mutect2, varscan2
- ECPAS | c.22+11168C>T | Intron (SNP) | VAF 45/115 reads (39%) | called by muse, mutect2, varscan2
- ECPAS | c.22+11167C>A | Intron (SNP) | VAF 45/115 reads (39%) | called by muse, mutect2, varscan2
- EP400P1 | n.651G>T | RNA (SNP) | VAF 39/142 reads (27%) | called by muse, mutect2, varscan2
- EYS | c.862+25C>A | Intron (SNP) | VAF 41/104 reads (39%) | called by muse, varscan2
- FAM90A27P | n.790G>T | RNA (SNP) | VAF 47/73 reads (64%) | called by muse, mutect2, varscan2
- FGFR4 | c.436+13C>A | Intron (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- HNRNPA3P1 | n.795G>C | RNA (SNP) | VAF 48/143 reads (34%) | called by muse, mutect2, varscan2
- HTR3A | c.*221C>A | 3'UTR (SNP) | VAF 189/308 reads (61%) | called by muse, mutect2, varscan2
- IGF2 | c.-4+128G>T | Intron (SNP) | VAF 27/39 reads (69%) | called by muse, mutect2, varscan2
- IGF2 | c.-4+127C>T | Intron (SNP) | VAF 25/37 reads (68%) | called by muse, mutect2, varscan2
- KRT8P11 | n.625T>A | RNA (SNP) | VAF 44/174 reads (25%) | called by muse, mutect2, varscan2
- LCN1 | c.-1G>T | 5'UTR (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
- LINC00922 | n.921C>A | RNA (SNP) | VAF 69/162 reads (43%) | called by muse, mutect2, varscan2
- LUC7L3 | c.*33+208G>T | Intron (SNP) | VAF 61/171 reads (36%) | called by muse, mutect2, varscan2
- MAP7 | c.67+24471G>T | Intron (SNP) | VAF 59/190 reads (31%) | called by muse, mutect2, varscan2
- MTUS1 | c.2624-12746G>T | Intron (SNP) | VAF 93/155 reads (60%) | called by muse, mutect2, varscan2
- NELL1 | c.1549+54792G>T | Intron (SNP) | VAF 116/217 reads (53%) | called by muse, mutect2, varscan2
- NR0B1 | c.1169-936C>T | Intron (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- NSMCE2 | c.264+4734G>T | Intron (SNP) | VAF 53/256 reads (21%) | called by muse, mutect2, varscan2
- PCDH19 | c.-29G>T | 5'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- PDE2A | c.1538-110C>A | Intron (SNP) | VAF 62/104 reads (60%) | called by muse, mutect2, varscan2
- PLOD3 | c.*48G>T | 3'UTR (SNP) | VAF 118/182 reads (65%) | called by muse, mutect2, varscan2
- PMF1 | c.162-6686G>T | Intron (SNP) | VAF 36/124 reads (29%) | called by muse, mutect2, varscan2
- POM121 | chr7:72949442 del T | 3'Flank (DEL) | VAF 49/187 reads (26%) | called by mutect2, pindel*, varscan2
- PPP4R1L | n.290G>T | RNA (SNP) | VAF 155/312 reads (50%) | called by muse, mutect2, varscan2
- RGS13 | c.66-15T>C | Intron (SNP) | VAF 43/131 reads (33%) | catalogued as rs1229387078; called by muse, mutect2, varscan2
- SPATA31D5P | n.853C>T | RNA (SNP) | VAF 22/259 reads (8%) | called by muse, mutect2
- SPEN | c.404+1112G>C | Intron (SNP) | VAF 95/320 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.10360+4164A>T | Intron (SNP) | VAF 52/219 reads (24%) | called by muse, mutect2, varscan2
- UBE2DNL | n.46G>T | RNA (SNP) | VAF 15/22 reads (68%) | called by muse, mutect2, varscan2
